Somatic mutation profile of tumor specimen 0DA699 from CCDI case PBBJRM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,338 days).
Specimen 0DA699: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fec4c8a0-ba81-4a35-a0aa-4b4594995533.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA69A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbd2daed-8ed4-4a79-a4a2-a6e8ed5c8c4d

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC006059.2 | c.776G>C p.R259P | Missense Mutation (SNP) | VAF 52/552 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59608180; called by muse, mutect2
- ZNF831 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 48/414 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as rs1289183394, COSV64041400; called by muse, mutect2, varscan2
- ATP9B | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.163); called by muse, mutect2, varscan2
